Surgical pathology report (de-identified scan), TCGA case TCGA-JW-AAVH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-AAVH-01A (Primary Tumor).

[page 1 of 5]
Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Component

Surgical Pathology

(note)

Name

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD-C3

Carcinoma, squamous cell,
non-keratinizing NOS 8072/3

Site: Cervix NOS C53.9

MD 2/19/14

PATHOLOGIC DIAGNOSIS

A. LEFT PARAMETRIUM, EXCISION:

- BENIGN FIBROADIPOSE TISSUE

B. UTERUS, BILATERAL FALLOPIAN TUBE AND OVARIES, RADICAL
HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:

UTERUS:

- CERVIX

- INVASIVE SQUAMOUS CELL CARCINOMA

- TUMOR SIZE: 3.0 CM IN GREATEST DIMENSION
(SEE COMMENT)

- NONKERATINIZING

- MODERATELY DIFFERENTIATED

- MARGINS UNINVOLVED (SEE COMMENT)

- LYMPHATIC INVASION PRESENT, MULTIFOCAL

- SEE CAP SYNOPSIS REPORT

- ENDOMETRIUM

- DISORDERED PROLIFERATIVE ENDOMETRIUM

- MYOMETRIUM

- LEIOMYOMA, 1.5 CM IN GREATEST DIMENSION

- SEROSA

- NO DIAGNOSTIC PATHOLOGIC ALTERATION IDENTIFIED

- RIGHT OVARY:

- BENIGN UNILOCULAR FOLLICULAR CYST

- RIGHT FALLOPIAN TUBE:

- BENIGN PARATUBAL CYST

- LEFT OVARY:

- NO DIAGNOSTIC PATHOLOGIC ALTERATION IDENTIFIED

- LEFT FALLOPIAN TUBE

- NO DIAGNOSTIC PATHOLOGIC ALTERATION IDENTIFIED

C. LYMPH NODES, LEFT PELVIC, REGIONAL DISSECTION:

- SIX BENIGN LYMPH NODES IDENTIFIED (0/6)

D. LYMPH NODES, RIGHT PELVIC, REGIONAL DISSECTION:

[page 2 of 5]
- NINE BENIGN LYMPH NODES IDENTIFIED (0/9)

PATHOLOGIC STAGING:

Primary Tumor (pT): pT1b1

Regional Lymph Nodes (pN): pN0

Number of lymph nodes examined: 15

Number of lymph nodes involved: 0

Distant Metastasis (pM): Not applicable

Pathologic Stage Grouping: IB1

Staff Pathologist

Comment

The grossly visible cervical squamous cell carcinoma, which measures 3.0 x 2.5 x 1.2 cm, is microscopically located 1.5 mm from the nearest inked serosa. The tumor extends to a maximum depth of 12 mm in a 13.5 mm thick section of cervix (section B13). The invasive carcinoma is grossly located 2.0 cm from the nearest vaginal cuff margin.

Pertinent Clinical Information

-year-old female with cervical cancer

Clinical Impression: SCCA

Gross Description

Specimen Material: A. Left parametrium, B. Radical hysterectomy, bilateral tubes and ovaries, C. Left pelvic lymph node, D. Right pelvic lymph node

The case is received in four parts, each labeled with the patient's name, medical record number and given accession number and it is accompanied by a requisition form labeled with the same name and accession number.

Part A. Received in formalin labeled "LEFT PARAMETRIUM" is an irregular portion of fibrofatty tissue measuring 2.7 x 1.5 x 0.5 cm with an attached suture. Within the fibrofatty tissue, an elongated gray-white vessel is identified measuring 2.0 cm in length x 0.3 cm in diameter. There are no discrete masses seen within the lumen. The specimen is submitted in its entirety in cassettes A1-A3 with the vascular tissue adjacent to the suture inked black to facilitate the embedding process in A1.

Part B. Received in formalin labeled "RADICAL HYSTERECTOMY BILATERAL TUBES AND OVARIES", is a 148 gram, 9 cm from superior to inferior x 7 cm from cornu to cornu x 2.8 cm from anterior to posterior uterus with bilateral attached adnexa and attached cervix measuring 3.0 cm x 3.5 cm with a 0.7 cm slit-like external os. The anterior surface is inked blue and posterior surface is inked black. The serosa is tan-pink and hyperemic. The vaginal cuff is present measuring 4 x 1.2 cm x 0.2 cm. The parametrial tissue is present measuring 2 x 1 x 0.2 cm (right) and 1.5 x 1 x 0.5 cm (left). The endometrium measures 0.2 cm thick; no focal lesions are seen. The endometrial cavity measures 3 x 0.3 cm. There is a 1.5 x 1.2 cm gray-white circumscribed submucosal nodule; the cut surface displays whorled, firm, homogeneous tissue. The myometrium measures 1.5 cm thick.

The cervix displays a tan-yellow centrally ulcerative mass (3.0 x 2.5 x 1 cm) located on the posterior and anterior surface of the endocervix. The mass appears to invade to a depth of 1.2 cm but is grossly 0.4 cm from the

[page 3 of 5]
outer surface. The mass extends into the lower uterine segment. The mass is located approximately 1.0 cm from the lower uterine segment and 2.0 cm from vaginal cuff margin.

The right adnexa include a 4 x 2 x 1.5 cm ovary. The surface is tan-yellow, smooth, hyperemic and glistening. There is a 1.5 x 1 x 0.6 cm smooth unilocular cyst with serosanguineous fluid. The cut surface displays tan-white to tan-yellow soft homogeneous tissue. There is a 4 cm in length x 0.6 cm in diameter fimbriated right fallopian tube. The surface of the fallopian tube is tan-pink, smooth and hyperemic. The cut surface displays a pinpoint lumen.

The left adnexa include a 2 x 1.5 x 0.5 ovary with 4 cm in length, 0.6 cm in diameter fimbriated fallopian tube. The surface of the ovary is tan-yellow, smooth, and glistening; no lesion or excrescence is seen. The cut surface displays tan-white to tan-yellow unremarkable tissue. The left fallopian tube serosa is tan-pink, smooth and hyperemic. The cut surface displays a pinpoint lumen.

Representative sections are submitted as follows:

B1-B4 vaginal cuff margin in its entirety; clock designation: 12-3, 3-6, 6-9, 9-13

B5 right, parametrium tissue, en face

B6 left parametrial tissue, en face

B7-B10 anterior longitudinal section from fundus to cervix, sequentially from superior to inferior

B11-B14 posterior longitudinal section, sequentially from superior to inferior

B15 cervical, greatest depth of tumor invasion

B16 tumor to exocervix

B17 myometrial nodule

B18 right ovary

B19 right ovarian cyst

B20 right fallopian tube

B21- left ovary

B22 left fallopian tube

Part C. Received in formalin labeled "LEFT PELVIC LYMPH NODE" is an irregular portion of fibrofatty tissue measuring 6.5 x 0.8 cm. Within the fibrofatty tissue, multiple lymph nodes are identified ranging from 0.3 to 2 cm in greatest dimension. The lymph nodes are entirely submitted as follows: C1 four possible whole nodes

C2 two whole possible nodes

C3 two whole possible nodes

Part D. Received in formalin labeled "RIGHT PELVIC LYMPH NODE" is an irregular portion of fibrofatty tissue measuring 6.7 x 5.5 x 1.5 cm. Within the fibrofatty tissue, multiple possible lymph nodes are identified ranging from 0.4 to 2.2 cm in greatest dimension. The cut surface of the larger nodes displays fatty firm lymphoid tissue. The lymph nodes are submitted in their entirety as follows:

D1 five possible whole nodes

D2 three whole possible nodes

D3-D4 one serially sectioned possible node

D5 one bisected possible node

Pathology Assistant

[page 4 of 5]
Pathology Resident
Microscopic Description
A, C, D: Performed.

B. H&E stained sections show cervical invasive squamous cell carcinoma with lymphatic invasion. The endometrium shows a proliferative pattern with an occasional mildly dilated gland lumen; no atypia, hyperplasia or carcinoma is seen. The myometrium shows a leiomyoma without increased mitotic activity, atypia, increased cellularity or tumor necrosis found. Other than a benign right ovarian cyst, the fallopian tubes and ovaries are unremarkable.

CAP SYNOPSIS REPORT:

Specimen: Cervix, uterine corpus, both ovaries and fallopian tubes
Procedure: Radical hysterectomy
Tumor Size: Greatest dimension 3 cm; 2.5 x 1 cm
Tumor Site: All quadrants (essentially circumferential)
Histologic Type: Squamous cell carcinoma, nonkeratinized
Histological Grade: Moderately differentiated (G2)
Margins: Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1.5 mm (cervical serosa)
Lymphatic Invasion: Present, multifocal
Vascular Invasion: Not identified

TNM Pathologic Tumor Staging:

Primary Tumor (pT): pT1b1; Clinically visible lesion less than or equal to 4 cm in greatest dimension
Regional Lymph Node (pN): pN0
Number of Lymph Nodes Examined: 15
Number of Lymph Nodes Involved: 0
Distance Metastasis (pM): Not applicable
Stage Grouping: IB1

The staff pathologist listed below has reviewed this case.

Pathology Resident
Electronically Signed Out

Staff Pathologist

Result History

SURGICAL PATHOLOGY

- Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date

Order Time

Result Information

Result Date and Time

Status
Final result

Priority
Routine

Received Date/Time

Received Date

Received Time

Order Providers

[page 5 of 5]
Authorizing Provider

Encounter Provider
None

Encounter

[View Encounter](#)

Order

SURGICAL PATHOLOGY

Administration Details

No Administrations
Recorded

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
-----------------	-------------------	-----------------	---------------

Order Details

Frequency ONCE	Duration 1 occurrence	Priority Routine	Order Class Normal
-------------------	--------------------------	---------------------	-----------------------

Quantity

Ordering Quantity
1

Comments

Ordered by

Original Order

Ordered On	Ordered By
------------	------------

Collection Information

Collection Date	Collection Time	Resulting Agency
-----------------	-----------------	------------------

Provider Information

Ordering User	Ordering Provider	Authorizing Provider
Attending Provider(s)	Admitting Provider	PCP

Order-Level Documents:

There are no order-level documents.

Encounter

[View Encounter](#)

Orders Needing Specimen Collection

**** None ****

Criteria	12/30/13	Yes	No

Source: NCI Genomic Data Commons file cbfd2a52-229c-4f45-8d5f-6bd65eff603a (TCGA-JW-AAVH.DDB7F46F-ABEE-4B05-9993-96E68774AB40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).